Surgical pathology report (de-identified scan), TCGA case TCGA-23-1022, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1022-01A (Primary Tumor).

[page 1 of 6]
SURGICAL

PATIENT:

Hospital

Date of

Soc. Sec. :

Location:

Pathologist

Assistant:

Attending MD:

Ordering MD:

Copies To:

PATH

A/S:

Rec:

Col:

DIAGNOSIS:

1. OMENTUM, TUMOR, PARTIAL OMENTECTOMY:
-Metastatic papillary serous carcinoma
2. OMENTAL TUMOR, PARTIAL OMENTECTOMY:
-Metastatic papillary serious carcinoma
3. LEFT OVARY AND TUBE, LEFT SALPINGO-OOPHORECTOMY:
-Primary ovarian moderate to poorly differentiated papillary serous carcinoma with anaplastic features, high grade
-Maximum tumor dimension: 5.0 cm
-The tumor is bilateral (see specimen #4, right ovary/tube)
-The tumor involves the ovarian surface
-The tumor infiltrates paraovarian soft tissues
-The residual ovary shows senescent changes and focal tumor-associated granulomatous inflammation
-The left fallopian tube shows transmural involvement (mucosal and submucosal involvement is noted in the fimbriated end) with papillary serous carcinoma
-Extensive serosal involvement also noted
-The fallopian tube also shows, foci of atypical epithelium, intraluminal tufts of malignant cells admixed with histiocytes, chronic salpingitis and mesonephric duct remnants
-Extensive tumor infiltration in mesosalpinx is noted
-Extensive surface reactive mesothelial hyperplasia, surface fibrin, adhesions and associated acute and chronic inflammation
4. RIGHT TUBE AND OVARY, RIGHT SALPINGO-OOPHORECTOMY:
-Primary ovarian moderate to poorly differentiated papillary serous carcinoma, high grade
-Maximum tumor dimension: 4.5 cm
-The tumor is bilateral (see specimen #3, left ovary)
-The tumor extensively involves the right ovary which is virtually entirely replaced by tumor
-Scanty residual recognizable ovary noted
-The right fallopian tube shows serosal involvement by papillary serous carcinoma, chronic salpingitis with intraluminal

continued on next page)□

Page: 2

histiocytes, admixed tufts of malignant cells and mesonephric duct remnants

- Extensive tumor infiltrate in mesosalpinx with foci of vascular space invasion and extensive surface involvement
- Portion of appendix showing extensive tumor infiltration within muscular propria, serosa and mesoappendiceal fat with associated fibroadhesions
- No mucosal involvement of appendix noted
- Reactive mesothelial hyperplasia, and acute and chronic

[page 2 of 6]
inflammation

5. PERITONEAL IMPLANT, BIOPSY:
- Metastatic papillary serous carcinoma
6. APPENDIX EPIPLOICA, EXCISION:
- Metastatic papillary serous carcinoma
- Associated mesothelial-lined fibroadipose tissue showing mesothelial hyperplasia, acute and chronic inflammation and focal fat necrosis
7. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
- Endometrium:
- Inactive endometrium with eosinophilic metaplasia and associated acute and chronic inflammation (see comment)
- Endometrial polyp with associated intraluminal and stromal histiocytes
- Aggregates of stromal histiocytes
- Cervix:
- Chronic cervicitis with squamous metaplasia and stromal calcifications
- Myometrium:
- Leiomyoma with focal calcification, 1.2 cm in greatest dimension
- Serosa:
- Extensive anterior and posterior serosal involvement by papillary serous carcinoma with tumor-associated granulomatous inflammation with multinucleated giant cells
8. ASCENDING COLON, BIOPSY:
- Metastatic papillary serous carcinoma
- Associated mesothelial-lined fibrovascular, fibromuscular and fibroadipose tissue with foci of chronic inflammation
9. TRANSVERSE COLON, BIOPSY:
- Metastatic papillary serous carcinoma
- Associated mesothelial-lined fibrous connective and adipose tissue with chronic inflammation and reactive mesothelial hyperplasia
10. RIGHT PERIAORTIC NODE, BIOPSY:
- Metastatic papillary serous carcinoma present in one out of one (1/1) lymph node
11. RIGHT PELVIC LYMPH NODE, BIOPSY:
- Metastatic papillary serous carcinoma present in two out of three lymph nodes (2/3)
- Extracapsular vascular space invasion noted

(continued on next page)□

Page: 3

12. LEFT PELVIC LYMPH NODE, BIOPSY:
- Metastatic papillary serous carcinoma present in one out of one lymph node (1/1)
13. RIGHT SIDE WALL, BIOPSY:
- Metastatic papillary serous carcinoma
14. RIGHT GUTTER, BIOPSY:
- Metastatic papillary serous carcinoma
- Associated fibrovascular connective tissue, fibromuscular and fibroadipose tissue with extensive vascular space invasion and chronic inflammation
15. HEPATIC FLEXURE, BIOPSY:

[page 3 of 6]
-Metastatic papillary serous carcinoma

16. COLON FLEXURE, BIOPSY:

-Metastatic papillary serous carcinoma

17. MESENTERIC TUMOR, BIOPSY:

-Metastatic papillary serous carcinoma

18. APPENDIX, APPENDECTOMY:

-Metastatic papillary serous carcinoma infiltrating muscularis propria, serosa and mesoappendiceal fat
-No mucosal or submucosal tumor involvement present

19. UMBILICAL NODULE, EXCISION:

-Metastatic papillary serous carcinoma with tumor-associated prominent granulomatous inflammation, and multinucleated giant cell reaction

20. ANTERIOR ABDOMINAL WALL, BIOPSY:

-Metastatic papillary serous carcinoma
-Tumor infiltrates fibrovascular connective and adipose tissue with associated reactive mesothelial hyperplasia and chronic inflammation

21. INGUINAL LYMPH NODE, BIOPSY:

-Fragments of papillary serous carcinoma with tumor-associated granulomatous and chronic inflammation

COMMENT: has reviewed slide (P) and concurs with the diagnosis. Based on the material examined this patient is Stage IIIC T3c N1 Mx.

HISTORY: Pelvic mass

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM TUMOR

Labeled "omentum tumor", received fresh in the Operating Room for frozen section microscopy and subsequently fixed in formalin, is a 5.4 x 3.6 x 1.2 cm portion of indurated tan-yellow adipose tissue

continued on next page)□

Page: 4

which is almost entirely replaced by white firm tumor. Representative sections are submitted.

A. Frozen section control #1

B. Formalin-fixed tissue - 1

2: OMENTAL TUMOR

Labeled "omental tumor" and received in formalin is a 28 x 7 x 2 cm indurated and focally hemorrhagic portion of tan-yellow adipose tissue which is almost entirely replaced by white firm tumor. Representative sections are submitted.

C. 1

3: LEFT OVARY/TUBE

Labeled "left ovary/tube" and received in formalin is a 5.0 x 4.5 x 3.5 cm previously incised ovoid tan white tumor mass. The external surface is focally friable. On sectioning, the cut surfaces are friable, tan-white and papillary. No normal ovarian parenchyma is identified. On sectioning, a 3.5 cm in length and 0.4 cm in diameter non-fimbriated segment of fallopian tube is

[page 4 of 6]
identified within this tumor mass. Representative sections are submitted.

D,E. Tumor mass - 1 each
F. Fallopian tube - 2
GG-II. Tumor mass - multiple

4: RIGHT OVARY/TUBE

Labeled 'right ovary/tube' and received in formalin is an ovoid 4.5 x 3.0 x 3.0 cm previously incised tan white tumor mass. The external surface is friable. On sectioning, cut surfaces are friable, tan-white and papillary. No residual ovarian parenchyma is identified. On sectioning, there is a 4.5 cm in length and 0.5 cm in diameter fimbriated segment of fallopian tube embedded within the tumor mass. Representative sections are submitted.

G,H. Tumor mass - 1 each
I. Fallopian tube - 2
JJ-00. Tumor mass - 1 each

5: PERITONEAL IMPLANT

Labeled 'peritoneal implant' and received in formalin is a 0.9 x 0.5 x 0.4 cm friable pink-white tissue fragment. Entirely submitted.

J. 1

6: APPENDIX EPIPLOICA

Labeled 'appendix epiploica' and received in formalin is a 2.3 x 2.1 x 0.8 cm portion of tan indurated adipose tissue. Representative sections are submitted.

K. 2

7: UTERUS

Labeled 'uterus', received fresh in the Operating Room and subsequently fixed in formalin, is a 50 gram uterus and cervix without attached adnexa. The uterus is 6.2 cm from fundus to

continued on next page)□

Page: 5

ectocervix, 5.5 cm cornu to cornu, and 3.1 cm anterior to posterior. The serosa is diffusely roughened, tan-red with abundant adhesions and hemorrhage. The cervix is 2.3 cm in length and 1.4 cm in diameter with a 0.4 cm patent os. The transformation zone is distinct. The endocervical canal is 1.2 cm in length and is tan and rugose without obvious lesion. The endometrial cavity is 3.1 cm in length and 2.3 cm in diameter with a smooth, tan-red endometrium which displays a 0.1 cm average thickness. The myometrium measures up to 1.3 cm in thickness and contains a 1.2 cm in greatest diameter firm, tan-white, whorled intramural leiomyoma. On sectioning the leiomyoma, no areas of hemorrhage, necrosis or calcifications are identified. Also received is a separate 2.3 x 0.8 x 0.5 cm focally cauterized portion of smooth, tan-pink ectocervix. Representative sections.

L. Frozen section control #2 - 1
M. Anterior uterine corpus - 1
N. Anterior cervix - 1
O. Leiomyoma - 1
P. Posterior uterine corpus - 1
Q. Posterior cervix - 1
R. Additional fragment of ectocervix - 2

8: ASCENDING COLON

Labeled 'ascending colon' and received in formalin is a 2.1 x 1.1 x 0.8 cm firm tan-pink tissue fragment which, on sectioning, displays abundant firm white tumor. Representative section.

[page 5 of 6]
S. 1

9: TRANSVERSE COLON

Labeled "transverse colon" and received in formalin is a 1.7 x 1.2 x 0.8 cm indurated tan-red tissue fragment which, on sectioning, displays abundant firm white tumor. Representative section.

T. 1

10: RIGHT PERIAORTIC NODE

Labeled "right periaortic node" and received in formalin is a 3.6 x 1.7 x 1.2 cm markedly enlarged lymph node which is entirely replaced by firm white tumor. Representative section.

U. 1

11: RIGHT PELVIC NODE

Labeled "right pelvic node" and received in formalin are three firm tan-red lymph nodes ranging from 1.2 to 1.4 cm in greatest dimension. On sectioning, two lymph nodes display foci of firm white tumor. Representative sections are submitted.

V. 3

12: LEFT PELVIC NODE

Labeled "left pelvic node" and received in formalin is a 2.7 x 2.1 x 1.4 cm friable pink-white lymph node which is almost entirely replaced by friable white tumor. Representative section.

W. 1

ued on next page)□

Page: 6

13: RIGHT SIDE WALL

Labeled "right side wall" and received in formalin is a 2.5 x 1.3 x 0.8 cm indurated tan-pink tissue fragment which, on sectioning, is almost entirely replaced by firm white tumor. Representative sections are submitted.

X. 1

14: RIGHT GUTTER BIOPSY

Labeled "right gutter biopsy" and received in formalin is a 2.3 x 1.3 x 0.6 cm firm tan-red tissue fragment which, on sectioning, displays a homogeneous tan-pink cut surface. Entirely submitted.

Y. 3

15: HEPATIC FLEXURE

Labeled "hepatic flexure" and received in formalin is a 6.3 x 3.2 x 1.1 cm indurated tan-red fibrous tissue fragment which, on sectioning, displays focal areas of firm white tumor. Representative section.

Z. 1

16: COLON FLEXURE

Labeled "colon flexure" and received in formalin is a 1.6 x 0.8 x 0.7 cm firm tan-red tissue fragment which, on sectioning, displays abundant firm white tumor. Representative section.

AA. 1

17: MESENTERIC TUMOR

[page 6 of 6]
Labeled "mesenteric tumor" and received in formalin is a 5.5 x 5.0 x 1.6 cm portion of diffusely indurated adipose tissue. On sectioning, the cut surfaces are almost entirely replaced by firm white tumor. Representative section.

BB. 1

18: APPENDIX

Labeled "appendix" and received in formalin is a 4.3 x 2.6 x 2.4 cm portion of indurated tan-red shaggy tissue. On sectioning, a 1.6 cm in length, 1.5 cm in diameter appendix is identified with a 0.1 cm appendiceal lumen. The appendix is entirely surrounded by firm white tumor. Representative section.

CC. 1

19: UMBILICAL NODULE

Labeled "umbilical nodule" and received in formalin is a 3.5 x 1.6 x 1.2 cm indurated portion of firm pink-white fibrous tissue and yellow lobulated adipose tissue. On sectioning, there is partial replacement by firm pink-white tumor. Representative section.

DD. 1

20: ANTERIOR ABDOMINAL WALL

Labeled "anterior abdominal wall" and received in formalin is a 1.3 x 0.8 x 0.6 cm firm tan-pink tissue fragment. On sectioning, abundant
continued on next page)□

Page: 7

firm white tumor is identified. Representative section.

EE. 1

21: INGUINAL LYMPH NODE

Labeled "inguinal lymph node" and received in formalin is a 2.3 x 0.6 x 0.3 cm friable pink-white tissue fragment. No obvious lymph node parenchyma is identified. Entirely submitted.

FF. 1

Gross dictated by .

OPERATIVE CONSULT (FROZEN):

FS#1. Omentum tumor:

-Papillary adenocarcinoma

FS#2. Uterus:

-No carcinoma identified

Special Studies: Frozen Section

SNOMED Code: T- 87000, M-84413

See Also: None

Pathologist

I, , the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled:

Source: NCI Genomic Data Commons file 0e5b5ad3-8048-44ee-8a01-e35ceb598532 (TCGA-23-1022.1A674838-E992-4E9B-82AE-FAFA0AD3BF56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).